Somatic mutation profile of tumor specimen TCGA-36-2545-01A (aliquot TCGA-36-2545-01A-01D-1526-09) from TCGA case TCGA-36-2545, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 42.3 years (15,444 days).
Specimen TCGA-36-2545-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7b95de4-7852-4efb-ab65-ed29a14e66b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2545-10A (Blood Derived Normal), aliquot TCGA-36-2545-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80a5c42e-dac7-4bf5-85a3-593c61757ec5

The open-access MAF lists 78 somatic variants for this specimen: 63 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Frame Shift Del 6, In Frame Del 5, Nonsense Mutation 2, Splice Site 2, 5'Flank 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA3 | c.1628A>C p.N543T | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV57052012; called by muse, mutect2, varscan2
- AKR1C1 | c.65G>C p.G22A | Missense Mutation (SNP) | VAF 127/690 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV66498938; called by muse, mutect2, varscan2
- ANKRD53 | c.555C>G p.D185E | Missense Mutation (SNP) | VAF 222/596 reads (37%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.462); catalogued as COSV55536959; called by muse, mutect2, varscan2
- APMAP | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV99469033; called by muse, mutect2
- ARMCX5 | c.842T>C p.I281T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV55766316; called by muse, mutect2, varscan2
- ARPC2 | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as COSV55284213; called by muse, mutect2, varscan2
- ART4 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV57451606; called by muse, mutect2, varscan2
- ASB10 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 123/199 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV51995394; called by muse, mutect2, varscan2
- AZIN1 | c.276+2T>G p.X92_splice | Splice Site (SNP) | VAF 42/450 reads (9%) | catalogued as COSV100457763; called by muse, mutect2
- BCOR | c.2155G>T p.A719S | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.993); catalogued as COSV60704804; called by muse, mutect2, varscan2
- BRD1 | c.1195A>T p.N399Y | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV53456198; called by muse, mutect2, varscan2
- CCAR2 | c.2149T>G p.C717G | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52383833; called by muse, mutect2, varscan2
- CEP89 | c.2021A>T p.E674V | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59863389; called by muse, mutect2, varscan2
- CFAP46 | c.6188C>A p.A2063E | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV54150942, COSV99585612; called by muse, varscan2
- CNGB3 | c.2201G>T p.G734V | Missense Mutation (SNP) | VAF 123/918 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV60686027, COSV60687783; called by muse, mutect2, varscan2
- DCTN1 | c.3097C>G p.L1033V | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62620184; called by muse, mutect2, varscan2
- EOGT | c.1466C>T p.P489L (on ENST00000383701 / NM_001278689.2; = p.P405L on NM_173654.3) | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs199832969, COSV55150374, COSV99808582; called by muse, mutect2, varscan2
- EXT1 | c.316T>A p.F106I | Missense Mutation (SNP) | VAF 138/744 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV65477555; called by muse, mutect2, varscan2
- FEN1 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57250681; called by muse, mutect2, varscan2
- FOXM1 | c.1092G>C p.R364= | Splice Region (SNP) | VAF 75/211 reads (36%) | catalogued as COSV61205702; called by muse, mutect2, varscan2
- GOLIM4 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 71/573 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236933281, COSV58329133; called by muse, mutect2, varscan2
- GPLD1 | c.2507G>C p.S836T | Missense Mutation (SNP) | VAF 133/682 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV51234219; called by muse, mutect2, varscan2
- GPR32 | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV99567366; called by muse, mutect2
- IL21R | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs376045198; called by muse, mutect2, varscan2
- IPP | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.085); catalogued as rs1418433296, COSV63432371; called by muse, mutect2, varscan2
- ITGB4 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 75/390 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778748791, COSV52324269; called by muse, mutect2, varscan2
- IVL | c.415G>C p.V139L | Missense Mutation (SNP) | VAF 73/295 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs924844174, COSV64216011; called by muse, mutect2, varscan2
- MAGEA1 | c.926T>A p.V309D | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as COSV100756680; called by muse, mutect2
- MATN1 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | catalogued as COSV65650383; called by muse, mutect2, varscan2
- METTL21A | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374826319; called by muse, mutect2, varscan2
- METTL3 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV52968305, COSV52968707; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV54914283; called by muse, mutect2, varscan2
- PHYHD1 | c.854C>A p.P285H (on ENST00000372592 / NM_001100876.2; = p.P278T on NM_174933.4) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58280491; called by muse, mutect2, varscan2
- PPARD | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs372497373, COSV61099370; called by muse, mutect2, varscan2
- PRRC2A | c.4777G>C p.G1593R | Missense Mutation (SNP) | VAF 121/375 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.352); catalogued as COSV52989522; called by muse, mutect2, varscan2
- PTCHD4 | c.1946T>C p.F649S | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59781522; called by muse, mutect2, varscan2
- RC3H1 | c.123C>G p.C41W | Missense Mutation (SNP) | VAF 88/537 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51199142; called by muse, mutect2, varscan2
- SDK1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 84/137 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs148919634; called by muse, mutect2, varscan2
- SIK3 | c.2609C>A p.S870Y (on ENST00000445177 / NM_001366686.2; = p.S828Y on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as COSV52612127; called by muse, mutect2, varscan2
- STAB1 | c.3807+1G>T p.X1269_splice | Splice Site (SNP) | VAF 43/105 reads (41%) | catalogued as rs1368314824, COSV58734500; called by muse, mutect2, varscan2
- SYCP1 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as COSV65694210, COSV65696388; called by muse, mutect2, varscan2
- TBX21 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 97/157 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99456294; called by muse, mutect2, varscan2
- TBX21 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 99/158 reads (63%) | catalogued as COSV51596346, COSV99456296; called by muse, mutect2, varscan2
- TEKT4 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 97/261 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs112344899; called by muse, mutect2, varscan2
- TGM7 | c.527T>G p.F176C | Missense Mutation (SNP) | VAF 131/276 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as COSV71772695; called by muse, mutect2, varscan2
- TNN | c.1536G>C p.W512C | Missense Mutation (SNP) | VAF 124/406 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53424305; called by muse, mutect2, varscan2
- TP53 | c.1043del p.L348Wfs*22 | Frame Shift Del (DEL) | VAF 52/103 reads (50%) | catalogued as COSV52736234, COSV53072454, COSV99425698; called by mutect2, pindel, varscan2
- XRCC6 | c.589G>C p.G197R | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63752650; called by muse, mutect2, varscan2
- ZBED9 | c.3134A>G p.N1045S | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as COSV101509382; called by muse, mutect2
- ZMYND19 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 84/127 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as rs745468866, COSV53811325, COSV53812392; called by muse, mutect2, varscan2
- ZNF232 | c.1082G>A p.C361Y | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV51502953; called by muse, mutect2, varscan2
- ZNF26 | c.1510C>A p.H504N | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60806672; called by muse, mutect2, varscan2
- ZNF792 | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV101289683, COSV68693019; called by muse, mutect2, varscan2
- CCDC87 | c.1154_1171del p.V385_A390del | In Frame Del (DEL) | VAF 34/138 reads (25%) | called by pindel, varscan2
- ERCC4 | c.2371_2373del p.L791del | In Frame Del (DEL) | VAF 42/152 reads (28%) | called by pindel, varscan2
- PDIA4 | c.328_331del p.D110Kfs*24 | Frame Shift Del (DEL) | VAF 43/370 reads (12%) | called by mutect2, pindel, varscan2
- PKLR | c.1310_1334del p.L437Rfs*3 | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | called by mutect2, pindel, varscan2
- PLXND1 | c.695_719del p.F232Sfs*41 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- PTPRZ1 | c.3413_3439del p.T1138_A1146del | In Frame Del (DEL) | VAF 31/290 reads (11%) | called by mutect2, pindel
- SEC31B | c.1274_1286del p.T425Nfs*3 | Frame Shift Del (DEL) | VAF 25/135 reads (19%) | called by mutect2, pindel, varscan2
- SPOCD1 | c.1522_1524del p.M508del | In Frame Del (DEL) | VAF 25/48 reads (52%) | called by mutect2, pindel, varscan2
- STK31 | c.1483_1520del p.L495Gfs*6 | Frame Shift Del (DEL) | VAF 65/227 reads (29%) | called by mutect2, pindel
- TJAP1 | c.665_703del p.A222_R234del (on ENST00000372445 / NM_001146016.1; = p.A212_R224del on NM_080604.3) | In Frame Del (DEL) | VAF 33/195 reads (17%) | called by mutect2, pindel
- ABCA4 | c.2343C>A p.A781= | Silent (SNP) | VAF 114/400 reads (29%) | catalogued as COSV64672654; called by muse, mutect2, varscan2
- ARHGAP4 | c.2682A>G p.P894= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV61686015; called by muse, mutect2, varscan2
- ATP10A | c.3774G>A p.P1258= | Silent (SNP) | VAF 90/272 reads (33%) | catalogued as rs768985513, COSV63515862; called by muse, mutect2, varscan2
- MAGEA1 | c.927C>G p.V309= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV100756679; called by muse, mutect2
- NTRK1 | c.1485A>G p.Q495= | Silent (SNP) | VAF 51/319 reads (16%) | catalogued as COSV62324804; called by muse, mutect2, varscan2
- PTPRF | c.2556C>T p.G852= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV63444153; called by muse, mutect2, varscan2
- SLC26A5 | c.1342C>T p.L448= | Silent (SNP) | VAF 99/411 reads (24%) | catalogued as COSV59700204; called by muse, mutect2, varscan2
- SLC35A2 | c.579G>T p.R193= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV54429897; called by muse, mutect2, varscan2
- SORL1 | c.2811T>C p.D937= | Silent (SNP) | VAF 54/416 reads (13%) | catalogued as COSV52752292; called by muse, mutect2, varscan2
- TOR3A | c.648G>A p.L216= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV61679969; called by muse, mutect2, varscan2
- TRPM3 | c.2664G>A p.L888= (on ENST00000357533 / NM_001366142.2; = p.L731= on NM_020952.6) | Silent (SNP) | VAF 91/144 reads (63%) | catalogued as COSV62584017; called by muse, mutect2, varscan2
- UNKL | c.669C>A p.G223= | Silent (SNP) | VAF 48/67 reads (72%) | catalogued as COSV57019130; called by muse, mutect2, varscan2
- ZNF449 | c.756A>G p.L252= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV59346680; called by muse, mutect2, varscan2
- HAUS7 | c.961-400G>C | Intron (SNP) | VAF 38/263 reads (14%) | catalogued as COSV57848350; called by muse, mutect2, varscan2
- MICD | chr6:29975311 C>T | 5'Flank (SNP) | VAF 18/208 reads (9%) | catalogued as rs748205193; called by muse, mutect2
